TARGET case TARGET-30-PAMNAL — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/4c881352-aa40-5bdb-907f-6e2b530aa805

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 3.4 years (1,235 days); Year of diagnosis: 2003; Days to last follow up: 4,499 days (12.3 years); INSS stage: Stage 4.

Biospecimens (2 samples)
- Sample TARGET-30-PAMNAL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAMNAL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
